Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A617, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A617-01A (Primary Tumor).

Tumor ID

Addendum Discussion

The calculated MIB-1 labeling index is 3.0% consistent with a low grade oligodendroglioma.

Addendum Diagnosis:

Right Insular Tumor, including enhancing region

Oligodendroglioma (who grade II)

MIB-1 LI= 3.0%

Microscopic Description:

Sections demonstrate gray and white matter that is diffusely infiltrated by a mildly to moderately hypercellular glial neoplasm. The majority of the tumor cells have round nuclei with only mild atypia. Perinuclear halos are prominent in most. A minority component is a fibrillary astrocytoma phenotype or a gemistocytic phenotype. In these sections, no mitosis are seen and there is no microvascular proliferation or necrosis. A neo plastic ganglion cell component is not seen. Eosinophilic granular bodies are not identified.

ICD-O-3
Oligodendroglioma NOS
9450/3
Site: Supratentorial NOS
C71.0
JW 4/6/13

Criteria	Yns	No
Primary / Tumor Site Discrepancy		
Case # (click):		

3/29/13
JW
3/29/13

Source: NCI Genomic Data Commons file ae265e42-94f9-4ab6-8a0d-d76387b3508d (TCGA-HT-A617.0DF6A8BE-1AE0-40CE-98D1-5B17DCB44FE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).